Somatic mutation profile of tumor specimen MMRF_1659_3_BM_CD138pos (aliquot MMRF_1659_3_BM_CD138pos_T1_KBS5U_L05365) from MMRF case MMRF_1659, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.0 years (18,618 days).
Specimen MMRF_1659_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a57b211-d480-44e5-be99-bab6b27f2152.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1659_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1659_2_PB_Whole_C1_KBS5U_L04831; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efc91ca4-f5ac-4803-9a5a-ff1cee413d3a

The open-access MAF lists 139 somatic variants for this specimen: 62 protein-altering or splice-affecting, 19 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 38, Silent 19, Intron 11, 3'Flank 3, Nonsense Mutation 2, RNA 2, 5'UTR 2, 5'Flank 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1280350283, COSV99568395; called by muse, mutect2, varscan2
- C2orf16 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as COSV68646836; called by muse, mutect2
- CACNA1I | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as rs1196906789, COSV60807504; called by muse, mutect2, varscan2
- CANX | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs775569975; called by muse, mutect2, varscan2
- CNTN3 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 100/159 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1388559105; called by muse, mutect2, varscan2
- CNTN6 | c.1253dup p.S419Vfs*33 | Frame Shift Ins (INS) | VAF 42/212 reads (20%) | catalogued as rs758676375; called by mutect2, varscan2
- FAM151B | c.444A>C p.K148N | Missense Mutation (SNP) | VAF 92/145 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV56474476; called by muse, mutect2, varscan2
- GALNTL6 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs756041431; called by muse, mutect2, varscan2
- HM13 | c.799G>C p.V267L | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59437482; called by muse, mutect2, varscan2
- HNF1B | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374126219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371486752; called by muse, varscan2
- IGHV5-51 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs549973566; called by muse, varscan2
- IQCH | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 66/581 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99971954; called by muse, mutect2, varscan2
- IRAK1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs782207964; called by muse, mutect2, varscan2
- KLK10 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs755105316; called by muse, mutect2, varscan2
- NEURL1B | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1435562072, COSV63940375; called by muse, mutect2, varscan2
- OR13C3 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101053300, COSV66166122; called by muse, mutect2, varscan2
- RNF113B | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1167910497, COSV57434659; called by muse, mutect2, varscan2
- ROBO1 | c.3971C>T p.T1324M | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1045339363, COSV71392720, COSV71397929; called by muse, mutect2, varscan2
- RPS9 | c.-25-8C>T | Splice Region (SNP) | VAF 47/176 reads (27%) | catalogued as COSV100256467; called by muse, mutect2, varscan2
- SPO11 | c.1002G>T p.R334S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100625710; called by muse, mutect2, varscan2
- TRAF3IP3 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50551452, COSV50551537; called by muse, mutect2, varscan2
- UNC5A | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149303258; called by muse, mutect2, varscan2
- USP29 | c.2658del p.I887Ffs*6 | Frame Shift Del (DEL) | VAF 30/185 reads (16%) | catalogued as COSV54146677; called by mutect2, pindel, varscan2
- VPS13D | c.13090G>A p.A4364T | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1341144908; called by muse, mutect2
- ZNF493 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100828552, COSV62749591; called by muse, mutect2, varscan2
- ABCC6 | c.1721T>C p.L574P | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ASH1L | c.3877G>A p.E1293K | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- C17orf98 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CABIN1 | c.3478C>G p.Q1160E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCDC152 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CCDC96 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 158/308 reads (51%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.216); called by mutect2, varscan2
- CEP290 | c.7249G>A p.D2417N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by mutect2, varscan2
- CFHR2 | c.737A>T p.H246L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DTX1 | c.46_60del p.G16_Q20del | In Frame Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- ESRP1 | c.1383C>G p.I461M | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM189A1 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GIPC3 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV6-57 | c.326A>C p.Y109S | Missense Mutation (SNP) | VAF 156/162 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- KCNH8 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT76 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 71/130 reads (55%) | called by muse, mutect2, varscan2
- LEXM | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MOXD1 | c.571A>T p.N191Y | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MRPL54 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- MYEOV | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 114/428 reads (27%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NETO1 | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 69/305 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- OR52A1 | c.125T>C p.I42T | Missense Mutation (SNP) | VAF 13/409 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2
- PSME1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- RARA | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- SAFB | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 90/382 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SH2D3C | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- SLF1 | c.2626G>T p.V876L | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SMAD6 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 116/493 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK35 | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STX12 | c.188+2T>C p.X63_splice | Splice Site (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- SYNJ2 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TACC2 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by mutect2, varscan2
- TCHH | c.16A>T p.R6* | Nonsense Mutation (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- USPL1 | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMIZ2 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 91/150 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF157 | c.251A>C p.E84A | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ZNF462 | c.6900C>A p.F2300L | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANK2 | c.7209T>C p.I2403= | Silent (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- ANKRD18A | c.144G>T p.A48= | Silent (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- CCR6 | c.612C>T p.V204= | Silent (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- CYP2F1 | c.1212G>A p.T404= | Silent (SNP) | VAF 31/277 reads (11%) | catalogued as rs541959207; called by muse, mutect2, varscan2
- ERVV-2 | c.1110C>T p.L370= | Silent (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- HAS1 | c.1557C>A p.R519= | Silent (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.60G>A p.E20= | Silent (SNP) | VAF 118/244 reads (48%) | catalogued as rs75660488; called by muse, varscan2
- INAVA | c.1425C>T p.P475= | Silent (SNP) | VAF 166/249 reads (67%) | catalogued as rs201583008, COSV66256355; called by muse, mutect2, varscan2
- LCMT2 | c.147A>G p.A49= | Silent (SNP) | VAF 54/342 reads (16%) | catalogued as COSV59789759; called by muse, mutect2, varscan2
- MEGF6 | c.3432T>C p.T1144= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- OVOL1 | c.453C>T p.C151= | Silent (SNP) | VAF 91/413 reads (22%) | catalogued as rs545994680; called by muse, mutect2, varscan2
- PIEZO2 | c.1158G>A p.R386= | Silent (SNP) | VAF 43/176 reads (24%) | called by muse, mutect2, varscan2
- POU2F3 | c.93G>A p.E31= | Silent (SNP) | VAF 72/247 reads (29%) | catalogued as rs777939631; called by muse, mutect2, varscan2
- QKI | c.63G>A p.L21= | Silent (SNP) | VAF 54/181 reads (30%) | called by muse, varscan2
- RGS19 | c.504G>A p.K168= | Silent (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- SH3TC2 | c.2298G>A p.V766= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- TIAM1 | c.4125G>A p.L1375= | Silent (SNP) | VAF 65/120 reads (54%) | called by muse, mutect2, varscan2
- TMX3 | c.1347A>G p.L449= | Silent (SNP) | VAF 57/159 reads (36%) | catalogued as rs769144543; called by muse, mutect2, varscan2
- ZSCAN29 | c.1944G>A p.E648= | Silent (SNP) | VAF 80/375 reads (21%) | catalogued as rs1163160654; called by muse, mutect2, varscan2
- ABCC4 | c.*748A>G | 3'UTR (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.*1763A>C | 3'UTR (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- AGR2 | c.*399C>T | 3'UTR (SNP) | VAF 69/162 reads (43%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*3942T>A | 3'UTR (SNP) | VAF 35/78 reads (45%) | catalogued as COSV58072376; called by muse, mutect2, varscan2
- BBS1 | c.1339+107G>A | Intron (SNP) | VAF 67/191 reads (35%) | catalogued as rs760183317; called by muse, mutect2, varscan2
- BCAT1 | c.*5564T>C | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- BLOC1S5 | c.*442G>A | 3'UTR (SNP) | VAF 12/67 reads (18%) | called by mutect2, varscan2
- BTN3A1 | c.*541G>A | 3'UTR (SNP) | VAF 38/151 reads (25%) | called by muse, mutect2, varscan2
- C10orf53 | c.*1564C>T | 3'UTR (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- C6orf120 | c.*228T>A | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- DIO2 | c.*4389C>G | 3'UTR (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- DNAH10 | c.9645-857C>T | Intron (SNP) | VAF 27/257 reads (11%) | catalogued as rs1278003723; called by muse, mutect2, varscan2
- DNAJB14 | c.*679G>A | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- EIF2AK3 | c.*512A>G | 3'UTR (SNP) | VAF 31/109 reads (28%) | catalogued as rs1198192467; called by muse, mutect2, varscan2
- EVC | c.1563+1914G>A | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- FOXI1 | c.*181C>A | 3'UTR (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- FOXL1 | c.*1365_*1379del | 3'UTR (DEL) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- GAPVD1 | c.3047-210A>C | Intron (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- HMGA2 | c.282+2158A>T | Intron (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- HSF4 | c.1255-80G>T | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs530911272; called by muse, mutect2, varscan2
- IFT80 | c.*317T>C | 3'UTR (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- IRF9 | c.*151G>T | 3'UTR (SNP) | VAF 59/215 reads (27%) | called by muse, mutect2, varscan2
- IZUMO3 | chr9:24545935 C>A | 5'Flank (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2
- KAZN | c.*1559C>T | 3'UTR (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- KIF21B | chr1:200970213 T>A | 3'Flank (SNP) | VAF 63/256 reads (25%) | called by muse, mutect2, varscan2
- KRTAP2-1 | c.*74G>A | 3'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- LILRA1 | c.*585G>T | 3'UTR (SNP) | VAF 36/229 reads (16%) | catalogued as rs189371015; called by muse, mutect2, varscan2
- LINC00303 | n.423G>A | RNA (SNP) | VAF 8/38 reads (21%) | catalogued as rs371441503; called by muse, mutect2
- LRRC28 | c.*1312G>A | 3'UTR (SNP) | VAF 63/235 reads (27%) | catalogued as rs771171841, COSV57343172; called by muse, mutect2, varscan2
- MBL2 | c.*1892C>T | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- MLLT3 | c.*3398A>G | 3'UTR (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- MLPH | c.*553C>A | 3'UTR (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- MMP27 | c.*6T>C | 3'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- MUC21 | c.*250C>T | 3'UTR (SNP) | VAF 21/114 reads (18%) | catalogued as rs760272681; called by muse, mutect2, varscan2
- MXD3 | chr5:177305703 C>G | 3'Flank (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- NDN | c.*527G>A | 3'UTR (SNP) | VAF 36/191 reads (19%) | catalogued as rs997240609; called by muse, mutect2, varscan2
- NKTR | c.*867G>T | 3'UTR (SNP) | VAF 9/122 reads (7%) | catalogued as COSV51775284; called by muse, mutect2
- NMRK1 | c.*2G>A | 3'UTR (SNP) | VAF 76/255 reads (30%) | catalogued as COSV100738049; called by muse, mutect2, varscan2
- NRXN1 | c.-685T>A | 5'UTR (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- NRXN2 | c.1197+128C>T | Intron (SNP) | VAF 24/74 reads (32%) | catalogued as rs918102583; called by muse, mutect2
- NSD3 | c.1856-1345T>C | Intron (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- NSL1 | c.*11353C>T | 3'UTR (SNP) | VAF 13/67 reads (19%) | catalogued as rs371938400; called by muse, mutect2, varscan2
- PRAM1 | c.*18C>T | 3'UTR (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- PSMB11 | c.*534T>A | 3'UTR (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- RPL18A | c.329-81C>T | Intron (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- SESN3 | c.*5786del | 3'UTR (DEL) | VAF 41/161 reads (25%) | catalogued as rs909803134; called by mutect2, pindel, varscan2
- SMG1 | c.*4455G>A | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- SMG5 | c.*1082G>A | 3'UTR (SNP) | VAF 47/157 reads (30%) | called by muse, mutect2, varscan2
- SOWAHA | c.*578T>C | 3'UTR (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- SPTLC1 | c.-31T>C | 5'UTR (SNP) | VAF 40/122 reads (33%) | called by muse, mutect2, varscan2
- TBX3 | chr12:114683787 C>A | 5'Flank (SNP) | VAF 32/66 reads (48%) | called by mutect2, varscan2
- TH | c.406-18C>A | Intron (SNP) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- UBASH3B | c.*323A>C | 3'UTR (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- VEGFA | c.546-85T>A | Intron (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- VEZT | c.*431_*434del | 3'UTR (DEL) | VAF 21/46 reads (46%) | called by pindel, varscan2
- WTAP | chr6:159761070 ins T | 3'Flank (INS) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- ZFPM2 | n.274G>T | RNA (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- ZNF516 | c.*1389T>A | 3'UTR (SNP) | VAF 61/110 reads (55%) | catalogued as COSV71587697; called by muse, mutect2, varscan2
